Gene-level copy-number profile of tumor specimen TCGA-AC-A4ZE-01A from TCGA case TCGA-AC-A4ZE, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 63.7 years (23,284 days).
Specimen TCGA-AC-A4ZE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.09a78982-3fe5-4dd0-be97-03b03a6bf683.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AC-A4ZE-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f3218517-8d85-45db-a906-7268a1ab9f38

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 8,759; copy number 3: 1,960; copy number 4: 46,007; copy number 6: 2,659; copy number 7: 80; copy number 9: 33; copy number 11: 19; copy number 13: 46; copy number 14: 112; copy number 16: 127; copy number 23: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AC-A4ZE-01A-11D-A41E-01): tumor purity 0.75, ploidy 3.85, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 346 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:60,789,805–61,681,049, 6 genes, copy number 13: AL512427.2, AL512427.1, RBBP4P3, AL356131.1, MTRNR2L9, KHDRBS2-OT1.
- chr6:61,870,097–61,893,882, 1 gene, copy number 13: AL355347.1.
- chr11:63,998,558–64,572,875, 39 genes, copy number 13 (within-gene range 2–13): MACROD1, AP000721.2, AP006333.2, FLRT1, AP006333.1, STIP1, FERMT3, TRPT1, NUDT22, AP001453.1, DNAJC4, VEGFB, FKBP2, AP001453.3, PPP1R14B, PPP1R14B-AS1, AP001453.2, PLCB3, BAD, GPR137, KCNK4, KCNK4-TEX40, Y_RNA, CATSPERZ, ESRRA, TRMT112, PRDX5, AP003774.2, CCDC88B, MIR7155, RPS6KA4, MIR1237, LINC02723, AP003774.1, LINC02724, AP005273.2, AP005273.1, AP006288.1, SLC22A11.
- chr11:66,421,004–68,616,711, 112 genes, copy number 9–14 (broad region; genes not listed).
- chr11:68,754,620–72,005,715, 99 genes, copy number 14–23 (within-gene range 4–23) (broad region; genes not listed).
- chr11:72,014,291–72,020,910, 1 gene, copy number 16: AP002490.1.
- chr11:72,685,069–73,298,625, 19 genes, copy number 11: ARAP1, ARAP1-AS1, AP003065.1, ARAP1-AS2, RPS12P20, STARD10, Y_RNA, MIR4692, AP002381.2, ATG16L2, FCHSD2, RNU6-672P, AP002381.1, AP002761.2, AP002761.1, P2RY2, AP002761.4, OR8R1P, P2RY6.
- chr11:75,399,515–75,815,406, 18 genes, copy number 16: RPS3, SNORD15B, KLHL35, GDPD5, AP002815.1, SERPINH1, AP001922.5, MAP6, AP001922.6, AP001922.2, AP001922.4, MOGAT2, RN7SL786P, AP001922.1, DGAT2, AP001922.3, AP003031.1, UVRAG-DT.
- chr11:75,835,215–75,837,645, 2 genes, copy number 16: Y_RNA, Y_RNA.
- chr11:76,782,251–76,798,153, 1 gene, copy number 16 (within-gene range 6–16): TSKU.
- chr11:76,800,364–78,582,156, 48 genes, copy number 16: AP003119.3, ACER3, AP002498.1, B3GNT6, CAPN5, OMP, MYO7A, GDPD4, TOMM20P1, PAK1, AP003680.1, CLNS1A, RNU7-59P, AQP11, RSF1, Y_RNA, RSF1-IT2, FTH1P16, RSF1-IT1, AP000580.1, AAMDC, AP002812.2, AP002812.3, AP002812.5, AP002812.1, INTS4, AP002812.4, AP003032.2, KCTD14, NDUFC2-KCTD14, AP003032.1, THRSP, NDUFC2, ALG8, RNU6-126P, KCTD21-AS1, KCTD21, USP35, GAB2, AP002985.1, AP003086.1, AP003086.3, AP003086.2, LINC02728, NARS2, AP003110.1, RNU6-311P, COPS8P3.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
